Somatic mutation profile of tumor specimen MP2PRT-PASJVB-TMP1-A (aliquot MP2PRT-PASJVB-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASJVB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,588 days).
Specimen MP2PRT-PASJVB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6542efb5-5279-41e1-8162-2b1ac2d71b1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASJVB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASJVB-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16bb22ed-6edb-4976-a5ce-04de5250d043

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.16294C>T p.R5432W | Missense Mutation (SNP) | VAF 16/336 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565753611, CM126448, COSV56411084; ClinVar: pathogenic; called by muse, mutect2
- CPA4 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs3735053, COSV55982848; called by muse, mutect2, varscan2
- DBX2 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 20/697 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV60339385; called by muse, mutect2
- EP300 | c.4538T>A p.L1513Q | Missense Mutation (SNP) | VAF 99/290 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54325421; called by muse, mutect2, varscan2
- EVPL | c.4040C>T p.A1347V | Missense Mutation (SNP) | VAF 58/793 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765962347, COSV56911335; called by muse, mutect2
- FAM83H | c.1867G>A p.G623S | Missense Mutation (SNP) | VAF 39/1066 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs1402507014; called by muse, mutect2
- GOLGA6L7 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as rs1190553315; called by muse, mutect2
- KRT71 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780977717, COSV57289616; called by muse, mutect2
- OR10AC1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 36/742 reads (5%) | SIFT deleterious, low confidence (0.01); catalogued as rs554886594; called by muse, mutect2
- RSU1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs138728566; called by muse, mutect2
- SLC12A8 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 29/371 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs753657542; called by muse, mutect2
- TENM4 | c.7612C>T p.R2538W | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376296325; called by muse, mutect2, varscan2
- UBQLN3 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 31/543 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs751563814, COSV61164599; called by muse, mutect2
- EIF4G3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- KATNIP | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- NLGN1 | c.1352C>G p.T451S | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.223); called by muse, mutect2
- PPP2R3A | c.697T>A p.L233M | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGEF28 | c.3930G>A p.A1310= | Silent (SNP) | VAF 18/247 reads (7%) | catalogued as rs182047082; called by muse, mutect2
- CDH2 | c.1038G>A p.T346= | Silent (SNP) | VAF 30/378 reads (8%) | catalogued as rs140193518; called by muse, mutect2
- DHCR24 | c.774G>A p.E258= | Silent (SNP) | VAF 25/432 reads (6%) | called by muse, mutect2
- GRWD1 | c.1179C>T p.D393= | Silent (SNP) | VAF 52/581 reads (9%) | catalogued as rs200076597, COSV53517995; called by muse, mutect2
- HNF1B | c.1440C>T p.S480= | Silent (SNP) | VAF 76/886 reads (9%) | catalogued as rs1167800723; called by muse, mutect2
- KCNV1 | c.684C>T p.A228= | Silent (SNP) | VAF 27/565 reads (5%) | called by muse, mutect2
- NRXN1 | c.3365-109728C>T | Intron (SNP) | VAF 18/256 reads (7%) | catalogued as COSV58454765, COSV58483796; called by muse, mutect2
